Somatic mutation profile of tumor specimen ALCH-AFF6-TTP1-A (aliquot ALCH-AFF6-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AFF6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.6 years (25,408 days).
Specimen ALCH-AFF6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d6eec2d-a178-4702-9cf2-4d7aa0551bce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFF6-NB1-A (Blood Derived Normal), aliquot ALCH-AFF6-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3205a37-4ce7-414e-a191-789ec2574421

The open-access MAF lists 120 somatic variants for this specimen: 89 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 19, Nonsense Mutation 9, Intron 6, 3'UTR 2, RNA 2, In Frame Del 2, 5'Flank 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 77/409 reads (19%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- AGO1 | c.2545G>C p.D849H | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV100940801; called by muse, mutect2, varscan2
- AKAP9 | c.8305G>A p.E2769K (on ENST00000359028; = p.E2745K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV62347339; called by muse, mutect2, varscan2
- ARID3C | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52406573; called by muse, mutect2
- COL24A1 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 16/109 reads (15%) | catalogued as COSV100993022; called by muse, mutect2, varscan2
- CRACD | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 29/415 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1167140878; called by muse, mutect2
- DCAF12L1 | c.1196G>T p.R399M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100948447; called by muse, mutect2, varscan2
- FLT4 | c.3148G>A p.V1050M | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs373876329; called by muse, mutect2, varscan2
- FOXO1 | c.1472T>A p.V491D | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); catalogued as COSV101091814; called by muse, mutect2, varscan2
- GRIA1 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1302659705; called by muse, mutect2, varscan2
- GRIA4 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.097); catalogued as rs763174108, COSV56895769; called by muse, mutect2
- GRK4 | c.868G>A p.V290I (on ENST00000398052 / NM_182982.3; = p.V258I on NM_005307.3) | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.033); catalogued as rs545770050; called by muse, mutect2, varscan2
- HTATSF1 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV99511336; called by muse, mutect2, varscan2
- INPP5J | c.1688C>T p.A563V (on ENST00000331075 / NM_001284285.2; = p.A195V on NM_001002837.2) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474656992; called by muse, mutect2, varscan2
- KDM5C | c.1772G>C p.G591A | Missense Mutation (SNP) | VAF 68/476 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV64763708, COSV64765815; called by muse, varscan2
- LILRA6 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752003009; called by muse, mutect2, varscan2
- MAMDC4 | c.2362C>T p.R788W (on ENST00000445819; = p.R709W on NM_206920.3) | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768466114, COSV56374527; called by muse, mutect2, varscan2
- MSH2 | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs63750849, CM030907; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- MYH1 | c.5169+1G>A p.X1723_splice | Splice Site (SNP) | VAF 20/147 reads (14%) | catalogued as rs111353752; called by muse, mutect2
- MYH7B | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409592158; called by muse, mutect2
- NAPSA | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.103); catalogued as COSV53796787; called by muse, mutect2
- NDUFA6 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs199507252; called by muse, mutect2
- OGDHL | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1040441881, COSV65101329; called by muse, mutect2
- PDE6C | c.2486_2488del p.E829del | In Frame Del (DEL) | VAF 38/272 reads (14%) | catalogued as rs1564806983; called by pindel, varscan2
- PPM1D | c.1349T>A p.L450* | Nonsense Mutation (SNP) | VAF 21/161 reads (13%) | catalogued as CD1414540, CM1414537, COSV100011246, COSV59954119; called by muse, mutect2, varscan2
- RNF145 | c.1048G>A p.V350I (on ENST00000424310 / NM_001199383.2; = p.V378I on NM_144726.2) | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.28); catalogued as rs778925094, COSV50864802; called by muse, mutect2
- SLCO1C1 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99858819; called by muse, mutect2
- SSX1 | c.157A>T p.R53* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | catalogued as rs782060573; called by muse, mutect2, varscan2
- TDRD6 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as rs917511523; called by muse, mutect2, varscan2
- TDRD6 | c.5812G>C p.E1938Q | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60175343; called by muse, mutect2, varscan2
- TINF2 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as rs200320654, COSV57471044; called by mutect2, varscan2
- TMEM132A | c.1099G>A p.V367I (on ENST00000453848 / NM_178031.3; = p.V368I on NM_017870.4) | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs773903804, COSV50008609; called by muse, mutect2, varscan2
- TNFRSF19 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99947581; called by muse, mutect2
- VN1R4 | c.160T>A p.F54I | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV60805387; called by muse, mutect2, varscan2
- VPS13C | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs760327607; called by muse, mutect2, varscan2
- ZNF577 | c.1351G>T p.V451L | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs764886645; called by muse, mutect2, varscan2
- ZNF585B | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV101087026; called by muse, mutect2
- ABCA3 | c.4795C>T p.Q1599* | Nonsense Mutation (SNP) | VAF 12/317 reads (4%) | called by muse, mutect2
- ADO | c.176C>G p.T59S | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AKAP11 | c.5521G>T p.A1841S | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AL645922.1 | c.2177A>T p.Y726F | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- BTN3A3 | c.364G>T p.G122* | Nonsense Mutation (SNP) | VAF 50/412 reads (12%) | called by muse, mutect2, varscan2
- CADM1 | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- CARNS1 | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2
- CAST | c.1466A>T p.K489I (on ENST00000341926; = p.K572I on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC171 | c.3000C>G p.F1000L | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- CCNB3 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CUX1 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CYP51A1 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DBH | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCAF12L1 | c.1197G>T p.R399S | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DECR1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DPH5 | c.494T>A p.I165N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCHO2 | c.682C>G p.H228D | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2
- FRMPD2 | c.3806C>G p.S1269* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by mutect2, varscan2
- FRMPD4 | c.1557G>C p.R519S | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GAS7 | c.218A>G p.E73G (on ENST00000432992 / NM_201433.2; = p.E13G on NM_201432.2) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.227); called by mutect2, varscan2
- GJD4 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GLE1 | c.609G>C p.E203D | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); called by muse, mutect2
- GNL3L | c.990C>A p.D330E | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GPR179 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- IL1RN | c.464C>G p.P155R (on ENST00000409930 / NM_173842.3; = p.P137R on NM_000577.5) | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INO80 | c.4549_4557delinsA p.P1517Kfs*4 | Frame Shift Del (DEL) | VAF 38/329 reads (12%) | called by pindel, varscan2*
- KNL1 | c.6809C>G p.S2270C (on ENST00000346991 / NM_170589.5; = p.S2244C on NM_144508.5) | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- KRT80 | c.1092dup p.K365Qfs*109 | Frame Shift Ins (INS) | VAF 23/185 reads (12%) | called by mutect2, pindel, varscan2
- LRP2 | c.9297C>A p.D3099E | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- MMP16 | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MUC16 | c.9128T>C p.L3043P | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); called by muse, mutect2
- NEXN | c.1392G>C p.Q464H | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOP58 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NRXN1 | c.807G>C p.M269I | Missense Mutation (SNP) | VAF 54/446 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTX4 | c.1169G>A p.R390K (on ENST00000447419 / NM_001328608.2; = p.R385K on NM_001013658.1) | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.237); called by muse, mutect2
- RASAL3 | c.167T>C p.M56T | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, varscan2
- RHOXF2 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- RPS6KA1 | c.2001G>C p.K667N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- SACS | c.12716C>A p.S4239Y | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SASH1 | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- SCPEP1 | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC25A21 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNX19 | c.2432A>G p.N811S | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORD | c.688C>G p.Q230E | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPG7 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 71/389 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SRSF1 | c.268C>G p.R90G | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SYNE1 | c.12853T>A p.L4285M (on ENST00000367255 / NM_182961.4; = p.L4214M on NM_033071.3) | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRD12 | c.771A>T p.E257D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- TET1 | c.1216G>C p.G406R | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR19 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2
- ZDBF2 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZFAND1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ACCSL | c.1411T>C p.L471= | Silent (SNP) | VAF 32/257 reads (12%) | called by muse, mutect2, varscan2
- AP1G2 | c.393C>T p.G131= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs1398046361; called by muse, mutect2, varscan2
- CACNA1A | c.1230C>T p.D410= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs751952553; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP2C8 | c.1140C>G p.L380= | Silent (SNP) | VAF 25/203 reads (12%) | catalogued as rs375186872; called by muse, mutect2, varscan2
- DECR1 | c.942G>C p.L314= | Silent (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- DMAC2 | c.498C>T p.L166= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- DNER | c.315T>C p.H105= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, varscan2
- IFT74 | c.348G>A p.Q116= | Silent (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2592C>A p.L864= (on ENST00000286628 / NM_001161352.2; = p.L806= on NM_002247.4) | Silent (SNP) | VAF 15/315 reads (5%) | catalogued as COSV54225906; called by muse, mutect2
- KIAA1109 | c.144T>C p.N48= | Silent (SNP) | VAF 39/285 reads (14%) | called by muse, mutect2, varscan2
- LGR6 | c.2433C>G p.V811= (on ENST00000367278 / NM_001017403.1; = p.V759= on NM_021636.3) | Silent (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- MAP1B | c.2040G>C p.V680= | Silent (SNP) | VAF 20/227 reads (9%) | called by muse, mutect2
- MED12L | c.5100G>C p.V1700= | Silent (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- MYBPH | c.1407G>A p.L469= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- PRRT3 | c.1905G>A p.P635= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs764472496; called by mutect2, varscan2
- RAI14 | c.348C>T p.D116= | Silent (SNP) | VAF 32/301 reads (11%) | catalogued as rs1170288232; called by muse, mutect2, varscan2
- SNAP29 | c.675A>G p.T225= | Silent (SNP) | VAF 37/358 reads (10%) | called by muse, mutect2, varscan2
- TSGA10 | c.912C>T p.I304= | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as COSV61825972; called by muse, mutect2, varscan2
- UCKL1 | c.1536C>G p.V512= | Silent (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- AC004951.3 | n.876C>T | RNA (SNP) | VAF 28/294 reads (10%) | catalogued as rs753238208; called by muse, mutect2, varscan2
- CCDC78 | c.493-28C>T | Intron (SNP) | VAF 70/329 reads (21%) | catalogued as COSV52403229; called by muse, mutect2, varscan2
- FAM189B | c.795-27A>G | Intron (SNP) | VAF 34/260 reads (13%) | called by muse, mutect2, varscan2
- FLYWCH1 | c.1514-590G>T | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- GLIPR2 | c.*398G>A | 3'UTR (SNP) | VAF 18/153 reads (12%) | catalogued as rs971229135; called by muse, mutect2, varscan2
- LILRB5 | c.1630-20C>G | Intron (SNP) | VAF 15/146 reads (10%) | called by muse, varscan2
- LINC01620 | n.289C>T | RNA (SNP) | VAF 15/127 reads (12%) | catalogued as rs928977773; called by muse, mutect2, varscan2
- OSGEP | c.411+652A>G | Intron (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- PERM1 | chr1:982089 C>A | 5'Flank (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- PLAGL2 | chr20:32190008 C>G | 3'Flank (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- TCEANC2 | c.*8172T>G | 3'UTR (SNP) | VAF 4/37 reads (11%) | catalogued as rs1299122292; called by mutect2, varscan2
- ZNF841 | c.-77-8538T>G | Intron (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
